Somatic mutation profile of tumor specimen SM-JU32P (aliquot 7316UP-293) from CPTAC case C259161, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Brain, NOS; Tumor grade: G4.
Specimen SM-JU32P: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19f2ea41-bdad-412a-bf0c-0d5c79f89098.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105283 (Blood Derived Normal), aliquot 7316UP-293-1105283; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a19b801d-b2f9-4fe6-935a-b0f498a372b1

The open-access MAF lists 120 somatic variants for this specimen: 83 protein-altering or splice-affecting, 22 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 22, Nonsense Mutation 7, Intron 5, RNA 5, Frame Shift Del 3, 3'Flank 2, Splice Region 2, 3'UTR 2, In Frame Del 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 27/118 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 220/478 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASAP3 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 42/359 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs148195646; called by muse, mutect2, varscan2
- BRCA2 | c.7386del p.N2463Ifs*4 | Frame Shift Del (DEL) | VAF 18/99 reads (18%) | catalogued as COSV66464724; called by mutect2, pindel, varscan2
- C7orf57 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV62363234; called by muse, mutect2, varscan2
- CDC14C | c.1125A>T p.R375S (on ENST00000428251; = p.R268S on NM_152627.3) | Missense Mutation (SNP) | VAF 37/315 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs755866926; called by muse, mutect2, varscan2
- CDH18 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1434063547, COSV56927210, COSV99931214; called by muse, mutect2, varscan2
- CFAP206 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs377549577, COSV51535435; called by muse, mutect2, varscan2
- CLCA4 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs374250322; called by muse, mutect2, varscan2
- CR2 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 32/226 reads (14%) | catalogued as rs1161576814, COSV65510786; called by muse, mutect2, varscan2
- CUX2 | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs1225937198, COSV55648814; called by muse, varscan2
- DUSP23 | c.441G>C p.Q147H | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs937893919; called by muse, mutect2
- EPHA8 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1394031937, COSV51263170; called by muse, mutect2, varscan2
- FARSA | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs868440760; called by muse, mutect2, varscan2
- HYDIN | c.10129C>T p.R3377C | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs779031423, COSV101151299, COSV101157939; called by muse, mutect2, varscan2
- IL4R | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs372988882; called by muse, mutect2, varscan2
- KCNU1 | c.2473G>A p.G825R | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs372670243; called by muse, mutect2, varscan2
- MMP13 | c.1325A>G p.Y442C | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781952022; called by muse, mutect2, varscan2
- PLCB4 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.854); catalogued as rs144345083; ClinVar: benign; called by muse, mutect2, varscan2
- PROP1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 221/650 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs372313496; called by muse, mutect2, varscan2
- SCN3A | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 45/238 reads (19%) | catalogued as COSV51820116; called by muse, mutect2, varscan2
- SCN7A | c.1496A>G p.H499R | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as rs959540957; called by muse, mutect2, varscan2
- SH3GL1 | c.987G>T p.E329D | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99515424; called by muse, mutect2, varscan2
- SLC36A3 | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 7/197 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100077637; called by muse, mutect2
- SPAM1 | c.101T>C p.L34S | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.132); catalogued as rs1258146565; called by muse, mutect2, varscan2
- TAF2 | c.1157T>C p.F386S | Missense Mutation (SNP) | VAF 76/371 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754007710; called by muse, mutect2, varscan2
- TBC1D28 | c.198+8C>T | Splice Region (SNP) | VAF 11/129 reads (9%) | catalogued as rs781038525; called by muse, mutect2
- TBX3 | c.806G>A p.R269Q (on ENST00000257566 / NM_016569.4; = p.R249Q on NM_005996.4) | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs775378442, COSV57469287; called by muse, mutect2
- WDSUB1 | c.400T>C p.C134R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as rs750682609; called by muse, mutect2, varscan2
- ZNF230 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV71273615; called by muse, mutect2, varscan2
- AADAC | c.1129T>A p.S377T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.057); called by muse, varscan2
- ACBD4 | c.152T>C p.M51T | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAM11 | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- AJM1 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- ANK1 | c.3405G>T p.E1135D | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ARAP2 | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARHGEF33 | c.2098G>C p.G700R | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C9orf78 | c.717C>G p.N239K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- CADM3 | c.340A>T p.T114S (on ENST00000368125 / NM_001127173.3; = p.T148S on NM_021189.5) | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARS1 | c.381G>C p.E127D | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC102A | c.793G>C p.V265L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- CDC25B | c.56T>A p.V19E | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- DDX3X | c.839A>T p.Q280L (on ENST00000399959; = p.Q281L on NM_001356.5) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DLGAP1 | c.870G>T p.E290D | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- DNALI1 | c.29_41del p.G10Afs*10 | Frame Shift Del (DEL) | VAF 30/294 reads (10%) | called by mutect2, pindel
- DOCK8 | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 56/208 reads (27%) | called by muse, mutect2, varscan2
- DOCK8 | c.2102C>G p.S701C | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- DOCK8 | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | called by muse, mutect2, varscan2
- EMD | c.180C>G p.S60R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM187A | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- FAM83H | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.372); called by muse, mutect2
- FILIP1 | c.148A>C p.M50L | Missense Mutation (SNP) | VAF 67/507 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLNB | c.2680A>G p.K894E | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GALNT18 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 47/251 reads (19%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- HMCN1 | c.2441_2443del p.C814del | In Frame Del (DEL) | VAF 26/232 reads (11%) | called by mutect2, pindel, varscan2
- HOXA3 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXD3 | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- HPR | c.168C>A p.Y56* | Nonsense Mutation (SNP) | VAF 12/273 reads (4%) | called by muse, mutect2
- IL1RAPL2 | c.900A>T p.I300= | Splice Region (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- ITGA11 | c.536T>A p.V179E | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- ITGA6 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 110/610 reads (18%) | SIFT tolerated (0.79); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ13 | c.730dup p.Y244Lfs*17 | Frame Shift Ins (INS) | VAF 22/127 reads (17%) | called by mutect2, pindel, varscan2
- KIF18A | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC27 | c.1080A>C p.K360N | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2
- NAV3 | c.6721C>T p.R2241* (on ENST00000397909 / NM_001024383.2; = p.R2219* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- NOTCH4 | c.3328T>A p.F1110I | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR52J3 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- PDLIM3 | c.8A>C p.Q3P | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PNISR | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); called by muse, mutect2
- RASGRP4 | c.395A>T p.H132L | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SI | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 42/421 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC7A14 | c.2186T>C p.F729S | Missense Mutation (SNP) | VAF 43/338 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNRNP200 | c.3071T>A p.F1024Y | Missense Mutation (SNP) | VAF 36/654 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TCTN2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TKTL2 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM181 | c.518T>G p.I173S | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- TMEM187 | c.255_292del p.K86Rfs*48 | Frame Shift Del (DEL) | VAF 15/139 reads (11%) | called by mutect2, pindel
- TMEM187 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 138/304 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- TNFRSF11A | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TPBG | c.1070T>A p.V357D | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UGT3A2 | c.933A>T p.E311D | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ZMYND19 | c.400A>C p.T134P | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZRANB3 | c.2899C>T p.L967F | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ACSM3 | c.1110G>T p.L370= | Silent (SNP) | VAF 26/337 reads (8%) | called by muse, mutect2
- ADAT3 | c.750C>T p.R250= | Silent (SNP) | VAF 30/196 reads (15%) | catalogued as rs767225266, COSV100280462; called by muse, mutect2, varscan2
- CDH1 | c.1095C>G p.V365= | Silent (SNP) | VAF 100/452 reads (22%) | called by muse, mutect2, varscan2
- CEACAM5 | c.1827G>A p.A609= | Silent (SNP) | VAF 47/207 reads (23%) | catalogued as rs782555811, COSV55752088; called by muse, mutect2, varscan2
- EPHB2 | c.426A>T p.A142= | Silent (SNP) | VAF 26/314 reads (8%) | catalogued as COSV65860839; called by muse, mutect2
- FOXL2 | c.648C>G p.A216= | Silent (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- GRIA1 | c.2079A>G p.P693= | Silent (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- GRIP2 | c.879C>T p.G293= (on ENST00000619221; = p.G196= on NM_001080423.4) | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as rs774000698, COSV56121182; called by muse, mutect2, varscan2
- KTN1 | c.3636A>G p.E1212= (on ENST00000395314 / NM_001271014.2; = p.E1183= on NM_004986.4) | Silent (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- MEFV | c.630G>C p.A210= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as rs770830323, COSV54819142; called by muse, mutect2, varscan2
- MMP10 | c.1176T>C p.S392= | Silent (SNP) | VAF 24/133 reads (18%) | called by muse, mutect2, varscan2
- NECAB2 | c.501C>T p.R167= | Silent (SNP) | VAF 35/239 reads (15%) | catalogued as rs755827646, COSV100534184; called by muse, mutect2, varscan2
- PARPBP | c.1164G>A p.T388= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs762271943; called by muse, mutect2, varscan2
- PCDHB12 | c.1398C>A p.P466= | Silent (SNP) | VAF 80/540 reads (15%) | catalogued as COSV53398333; called by muse, mutect2, varscan2
- RAG1 | c.2865C>T p.S955= | Silent (SNP) | VAF 59/299 reads (20%) | catalogued as COSV55025939; called by muse, mutect2, varscan2
- SALL1 | c.1665C>T p.V555= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as rs201565524, COSV51757309; called by muse, mutect2, varscan2
- SDC4 | c.27G>T p.L9= | Silent (SNP) | VAF 32/197 reads (16%) | called by muse, mutect2, varscan2
- SLC25A22 | c.732C>T p.N244= | Silent (SNP) | VAF 109/474 reads (23%) | called by muse, mutect2, varscan2
- STK10 | c.2244G>A p.E748= | Silent (SNP) | VAF 43/257 reads (17%) | called by muse, mutect2, varscan2
- TENT4A | c.1935C>T p.A645= | Silent (SNP) | VAF 18/310 reads (6%) | catalogued as rs140939839; called by muse, mutect2
- TNF | c.342C>T p.A114= | Silent (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- ZNF285 | c.1050G>A p.G350= | Silent (SNP) | VAF 45/169 reads (27%) | catalogued as rs1417500744; called by muse, mutect2, varscan2
- AC073348.1 | n.171T>A | RNA (SNP) | VAF 37/173 reads (21%) | called by muse, mutect2, varscan2
- CHRDL2 | c.1121-334C>A | Intron (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- CPEB2 | chr4:15001972 T>C | 5'Flank (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2
- DCHS2 | n.4989G>C | RNA (SNP) | VAF 23/169 reads (14%) | called by muse, mutect2, varscan2
- DOCK8 | c.1797+143C>T | Intron (SNP) | VAF 42/134 reads (31%) | called by muse, mutect2, varscan2
- F13A1 | c.1113-9236G>A | Intron (SNP) | VAF 43/174 reads (25%) | catalogued as rs375862509; called by muse, mutect2, varscan2
- GALM | c.346-1214G>A | Intron (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2, varscan2
- MEIS3 | c.*75C>T | 3'UTR (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- MS4A2 | c.538-48C>T | Intron (SNP) | VAF 27/166 reads (16%) | catalogued as rs751308080, COSV54012029; called by muse, mutect2
- NDUFAF5 | c.*1085A>G | 3'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- OR52Z1 | n.439A>T | RNA (SNP) | VAF 26/169 reads (15%) | called by muse, mutect2, varscan2
- RMDN1 | chr8:86470298 G>C | 3'Flank (SNP) | VAF 33/226 reads (15%) | called by muse, mutect2, varscan2
- RMDN1 | chr8:86470299 G>T | 3'Flank (SNP) | VAF 33/223 reads (15%) | called by muse, mutect2, varscan2
- SSPOP | n.14771C>T | RNA (SNP) | VAF 6/30 reads (20%) | catalogued as rs370703581; called by muse, mutect2, varscan2
- UGT2B27P | n.1491G>T | RNA (SNP) | VAF 101/533 reads (19%) | called by muse, mutect2, varscan2
